Somatic mutation profile of tumor specimen C3N-00646-02 (aliquot CPT0081980008) from CPTAC case C3N-00646, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.9 years (21,144 days).
Specimen C3N-00646-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 152cf293-61e4-47f3-9083-81ea94312281.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00646-71 (Blood Derived Normal), aliquot CPT0082030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/807a3121-99da-4c60-b0cd-f9a8d821b32e

The open-access MAF lists 81 somatic variants for this specimen: 61 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, Frame Shift Del 5, Nonsense Mutation 4, Splice Region 4, 3'UTR 3, Intron 2, RNA 1, 5'Flank 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHEB | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 21/219 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519950, COSV51262364, COSV51263550; ClinVar: likely pathogenic; called by muse, mutect2
- ACADM | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs796051897; called by muse, mutect2
- ACTL7B | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1480803021; called by muse, mutect2
- ATAD2 | c.415G>T p.V139F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.098); catalogued as COSV54881193; called by muse, mutect2, varscan2
- DDX50 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104424183; called by muse, mutect2
- EFR3A | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs1359496595; called by muse, mutect2, varscan2
- ELAVL4 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1345370346, COSV63914597; called by muse, mutect2
- GRIN3A | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62453111; called by muse, mutect2
- HS3ST2 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 15/212 reads (7%) | catalogued as rs1336994762, COSV54457839; called by muse, mutect2
- MCCD1 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs773573995, COSV66018785; called by muse, mutect2
- PAM | c.2627C>G p.P876R | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57216591; called by muse, mutect2
- PASD1 | c.2107G>T p.V703F | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1306096843; called by muse, mutect2
- RFX6 | c.1715C>A p.S572* | Nonsense Mutation (SNP) | VAF 24/368 reads (7%) | catalogued as COSV60585069; called by muse, mutect2
- SLC38A1 | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV67064301; called by muse, mutect2, varscan2
- TFE3 | c.114C>A p.L38= | Splice Region (SNP) | VAF 13/152 reads (9%) | catalogued as COSV59946412; called by muse, mutect2
- TFIP11 | c.1474A>T p.I492F | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV53226609; called by muse, mutect2, varscan2
- USP38 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761444526; called by muse, mutect2, varscan2
- ABCA1 | c.5935T>G p.S1979A | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2
- AKR1B1 | c.744C>A p.V248= | Splice Region (SNP) | VAF 18/487 reads (4%) | called by muse, mutect2
- C12orf40 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CALB2 | c.628-2A>T p.X210_splice | Splice Site (SNP) | VAF 6/125 reads (5%) | called by muse, mutect2
- CCDC149 | c.1217A>T p.D406V (on ENST00000635206 / NM_001330643.2; = p.D395V on NM_173463.5) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CCDC57 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.841); called by muse, mutect2
- CDCA2 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CLMN | c.2040G>T p.Q680H | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2
- CSTF2T | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 26/281 reads (9%) | called by muse, mutect2
- ENPEP | c.1021T>G p.Y341D | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EVI5 | c.1549A>G p.R517G | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBRS | c.722del p.P241Lfs*63 (on ENST00000287468; = p.P761Lfs*63 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 23/186 reads (12%) | called by mutect2, pindel, varscan2
- GGA3 | c.801del p.S267Rfs*43 (on ENST00000537686 / NM_138619.4; = p.S234Rfs*43 on NM_014001.5) | Frame Shift Del (DEL) | VAF 18/117 reads (15%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.9581T>C p.I3194T | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- GULP1 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2
- KIAA0100 | c.2530G>C p.V844L | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- KNOP1 | c.459_462del p.E154Kfs*58 | Frame Shift Del (DEL) | VAF 22/183 reads (12%) | called by mutect2, pindel
- LIPC | c.41T>C p.L14S | Missense Mutation (SNP) | VAF 34/349 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2
- LYPD3 | c.382+4C>A | Splice Region (SNP) | VAF 51/596 reads (9%) | called by muse, mutect2
- MAPK15 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.359); called by muse, mutect2
- MED13 | c.2971G>T p.A991S | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- MPV17L2 | c.223T>A p.F75I | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MUC17 | c.10990_10994del p.T3664Cfs*15 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- MYH7B | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); called by muse, mutect2
- OTOA | c.2187C>G p.D729E (on ENST00000286149; = p.D715E on NM_144672.4) | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PATJ | c.2947A>C p.S983R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- PCDHB6 | c.1348A>C p.T450P | Missense Mutation (SNP) | VAF 49/674 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2
- PDAP1 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); called by muse, mutect2
- PHF20 | c.361del p.Y121Mfs*4 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- PLEKHA4 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRELP | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2
- RALGAPA2 | c.3652C>T p.L1218F | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RGS14 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2
- RXRA | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 40/554 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2
- RYR2 | c.11177A>G p.Y3726C | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SDCCAG8 | c.824C>G p.T275S | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC1A5 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 29/345 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC6A14 | c.902C>G p.S301* | Nonsense Mutation (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- SPEM1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2
- SPINK4 | c.216-5C>T | Splice Region (SNP) | VAF 15/151 reads (10%) | called by muse, mutect2, varscan2
- TTC3 | c.5646T>G p.S1882R | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- ZNF750 | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF91 | c.2312A>G p.K771R | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ZSCAN29 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 33/353 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); called by muse, mutect2
- AKAP9 | c.6738G>A p.K2246= (on ENST00000359028; = p.K2222= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1262023240; called by muse, mutect2, varscan2
- FBN2 | c.3798C>T p.C1266= | Silent (SNP) | VAF 49/463 reads (11%) | called by muse, mutect2, varscan2
- FUT5 | c.147T>A p.L49= | Silent (SNP) | VAF 19/448 reads (4%) | called by muse, mutect2
- FZD9 | c.1248C>T p.F416= | Silent (SNP) | VAF 25/217 reads (12%) | catalogued as COSV60669665; called by muse, mutect2, varscan2
- GRIP1 | c.315T>C p.N105= | Silent (SNP) | VAF 10/298 reads (3%) | called by muse, mutect2
- MANBA | c.1986A>G p.K662= (on ENST00000642252; = p.K616= on NM_005908.4) | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as CD065752; called by muse, mutect2, varscan2
- MED13 | c.2292T>C p.R764= | Silent (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- PCDHA3 | c.84C>T p.S28= | Silent (SNP) | VAF 26/269 reads (10%) | catalogued as COSV65367526, COSV65368417; called by muse, mutect2
- PIEZO2 | c.5670C>T p.H1890= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as rs866759573; called by muse, mutect2
- PLEK | c.427C>T p.L143= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV99029643; called by muse, mutect2
- SNX25 | c.1617T>C p.V539= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs1248221421; called by muse, mutect2
- THEM4 | c.75G>A p.P25= | Silent (SNP) | VAF 25/228 reads (11%) | called by muse, mutect2
- CC2D1B | c.*386_*391del | 3'UTR (DEL) | VAF 13/122 reads (11%) | called by mutect2, pindel
- CCL4L2 | c.*202C>T | 3'UTR (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- CEACAM21 | c.-4G>A | 5'UTR (SNP) | VAF 21/237 reads (9%) | catalogued as rs1489304664; called by muse, mutect2
- DCAF17 | c.*602T>C | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- DLGAP4 | c.1648+15587_1648+15588del | Intron (DEL) | VAF 20/230 reads (9%) | called by mutect2, pindel, varscan2
- FAM205BP | n.923G>T | RNA (SNP) | VAF 38/494 reads (8%) | called by muse, mutect2
- FBRS | chr16:30662466 A>G | 5'Flank (SNP) | VAF 22/245 reads (9%) | called by muse, mutect2
- TIA1 | c.310+30A>G | Intron (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
